Somatic mutation profile of tumor specimen TCGA-DJ-A3US-01A (aliquot TCGA-DJ-A3US-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3US, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.3 years (13,634 days).
Specimen TCGA-DJ-A3US-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8111dd4e-210f-45de-affa-fa87611693f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3US-10A (Blood Derived Normal), aliquot TCGA-DJ-A3US-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a3670a4-ecab-4aa8-ac99-a856e141c817

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4BPA | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.133); catalogued as COSV65536075; called by muse, mutect2, varscan2
- HID1 | c.1562C>G p.S521C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59351270, COSV59351352; called by muse, mutect2, varscan2
- KRTAP6-2 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV58182099; called by muse, mutect2, varscan2
- NIBAN2 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs957168977, COSV64824106; called by muse, mutect2
- SMARCA5 | c.2467G>C p.A823P | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV51643194, COSV51646946; called by muse, mutect2, varscan2
- ZIC2 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.697); catalogued as COSV66254825; called by muse, mutect2, varscan2
- TGM6 | c.693A>T p.R231= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV52478578; called by muse, mutect2, varscan2
